Somatic mutation profile of tumor specimen MMRF_1980_1_BM_CD138pos (aliquot MMRF_1980_1_BM_CD138pos_T1_KBS5U_L07298) from MMRF case MMRF_1980, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.2 years (24,529 days).
Specimen MMRF_1980_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad45ef6f-aea1-4069-85ef-7bad16b4a65f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1980_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1980_1_PB_Whole_C2_KBS5U_L07292; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1c0c07b-4453-4b33-af73-5a8100486b47

The open-access MAF lists 139 somatic variants for this specimen: 54 protein-altering or splice-affecting, 15 silent, 70 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, 3'UTR 43, Silent 15, 5'UTR 10, Intron 10, 3'Flank 4, Splice Site 3, RNA 2, Splice Region 2, Nonsense Mutation 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACHE | c.1270C>T p.R424C | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.8); catalogued as rs761313292, COSV99574635; called by muse, mutect2, varscan2
- ADGRB1 | c.3521C>T p.S1174L | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60091842; called by muse, mutect2, varscan2
- CACNA2D2 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.158); catalogued as rs587610576, COSV56563573; called by muse, mutect2, varscan2
- CCDC168 | c.2063C>T p.T688I | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as rs1319855257; called by muse, mutect2, varscan2
- CCSER1 | c.161G>T p.G54V | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61479819; called by muse, mutect2
- EXOC1 | c.1159C>T p.R387* | Nonsense Mutation (SNP) | VAF 9/213 reads (4%) | catalogued as rs1425260892; called by muse, mutect2
- FAT2 | c.6683C>T p.T2228I | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.67); PolyPhen benign (0.259); catalogued as rs1301510347, COSV55820326; called by muse, mutect2, varscan2
- GDAP1 | c.625C>A p.L209I | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55187639, COSV99619246; called by muse, mutect2, varscan2
- HEPH | c.2074C>A p.L692I (on ENST00000343002; = p.L425I on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as rs1333056404; called by muse, mutect2, varscan2
- HS3ST4 | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs752319578, COSV58809556; called by muse, mutect2, varscan2
- IGLV3-1 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.175); catalogued as rs557374670; called by muse, varscan2
- IGLV3-1 | c.252C>G p.N84K | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as rs181381534; called by muse, varscan2
- LINC00910 | n.568C>T | Splice Region (SNP) | VAF 30/87 reads (34%) | catalogued as rs1024267970; called by muse, mutect2, varscan2
- MYT1 | c.1363G>T p.G455W | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60501082; called by muse, mutect2, varscan2
- NGEF | c.961G>A p.V321I | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.32); catalogued as rs569496752; called by muse, mutect2, varscan2
- PCDH19 | c.3203C>A p.P1068H (on ENST00000373034 / NM_001184880.2; = p.P1020H on NM_020766.3) | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs757057837, COSV55261220; called by muse, mutect2, varscan2
- RREB1 | c.4156G>A p.A1386T | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs1421884360; called by muse, mutect2, varscan2
- SPEN | c.2121A>C p.E707D | Missense Mutation (SNP) | VAF 17/226 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1375181959; called by muse, mutect2
- SULT1E1 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 67/219 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV56945916; called by muse, mutect2, varscan2
- TMEM74 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 20/263 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as rs1253392022, COSV52462147; called by muse, mutect2
- TRPA1 | c.1270G>A p.G424R | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs775817417; called by muse, mutect2, varscan2
- ZNF257 | c.704G>A p.G235E | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV71306327; called by muse, mutect2, varscan2
- ALDH3A1 | c.994C>A p.Q332K | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- C17orf75 | c.156del p.D54Tfs*62 | Frame Shift Del (DEL) | VAF 25/79 reads (32%) | called by mutect2, pindel, varscan2
- CCDC93 | c.659C>G p.A220G | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYP11B1 | c.871G>T p.A291S | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- DDHD2 | c.665G>T p.G222V | Missense Mutation (SNP) | VAF 61/169 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNA2 | c.2179G>T p.A727S | Missense Mutation (SNP) | VAF 4/75 reads (5%) | SIFT tolerated (0.65); PolyPhen benign (0.021); called by muse, mutect2
- DNAH10 | c.9881C>T p.A3294V (on ENST00000409039; = p.A3233V on NM_207437.3) | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DYNC2H1 | c.5111G>A p.G1704E | Missense Mutation (SNP) | VAF 54/256 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- FLT3 | c.1623C>A p.N541K | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- FOXN4 | c.187G>A p.G63S | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.033); called by muse, mutect2
- GNAT1 | c.631T>A p.F211I | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- GRK3 | c.1757A>G p.N586S | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- HCFC2 | c.1666_1666+19del p.X556_splice | Splice Site (DEL) | VAF 18/52 reads (35%) | called by mutect2, pindel
- IGHD3-10 | c.24A>C p.L8F | Missense Mutation (SNP) | VAF 8/11 reads (73%) | called by muse, mutect2, varscan2
- ITPRIPL1 | c.625G>C p.A209P (on ENST00000439118 / NM_001008949.3; = p.A217P on NM_178495.6) | Missense Mutation (SNP) | VAF 49/153 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- LRP2 | c.6116G>C p.G2039A | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- LRP2 | c.2723G>T p.G908V | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- MAN2A1 | c.862A>C p.I288L | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- MGAM | c.2522T>C p.I841T | Missense Mutation (SNP) | VAF 49/177 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- MRPL17 | c.112C>T p.R38W | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- MUC16 | c.1928C>T p.A643V | Missense Mutation (SNP) | VAF 71/155 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- OR11G2 | c.65A>C p.H22P | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- PIP5KL1 | c.580G>T p.D194Y | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLA2G4D | c.22G>A p.G8R | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2
- RSPRY1 | c.902-1G>A p.X301_splice | Splice Site (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2, varscan2
- SCN10A | c.1660C>A p.L554I | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- SEMA4F | c.671-1G>T p.X224_splice | Splice Site (SNP) | VAF 42/116 reads (36%) | called by muse, mutect2, varscan2
- SUMF2 | c.733+4A>T | Splice Region (SNP) | VAF 7/50 reads (14%) | called by muse, mutect2, varscan2
- UBTF | c.1425dup p.E476Rfs*14 | Frame Shift Ins (INS) | VAF 40/109 reads (37%) | called by mutect2, pindel, varscan2
- UMODL1 | c.1316C>A p.P439Q | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- UNC13A | c.2684C>T p.A895V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- ZKSCAN8 | c.1503G>C p.Q501H | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- ADAM12 | c.1962C>T p.V654= | Silent (SNP) | VAF 18/82 reads (22%) | called by muse, mutect2, varscan2
- ARHGAP32 | c.2898C>T p.A966= (on ENST00000310343 / NM_001378025.1; = p.A617= on NM_014715.4) | Silent (SNP) | VAF 22/228 reads (10%) | catalogued as COSV100088863; called by muse, mutect2
- BCL7A | c.36C>T p.S12= | Silent (SNP) | VAF 23/60 reads (38%) | called by muse, mutect2, varscan2
- ERV3-1 | c.480C>A p.S160= | Silent (SNP) | VAF 40/128 reads (31%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.81T>C p.G27= | Silent (SNP) | VAF 27/47 reads (57%) | called by muse, varscan2
- IGLL5 | c.84G>A p.L28= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as rs772288552, COSV73248990, COSV73251143; called by muse, mutect2, varscan2
- KRT75 | c.210G>T p.R70= | Silent (SNP) | VAF 18/86 reads (21%) | called by muse, mutect2, varscan2
- NEURL1 | c.63G>C p.R21= | Silent (SNP) | VAF 31/104 reads (30%) | called by muse, mutect2, varscan2
- NODAL | c.237C>T p.F79= | Silent (SNP) | VAF 26/140 reads (19%) | catalogued as COSV54662316; called by muse, mutect2, varscan2
- OSBPL10 | c.1749C>T p.H583= | Silent (SNP) | VAF 28/61 reads (46%) | catalogued as rs201483248; called by muse, mutect2, varscan2
- RYR1 | c.10866G>A p.K3622= | Silent (SNP) | VAF 42/103 reads (41%) | called by muse, mutect2, varscan2
- SARDH | c.2235G>T p.V745= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as rs978808997; called by muse, mutect2, varscan2
- TBC1D12 | c.240G>A p.Q80= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs1163671444; called by muse, mutect2, varscan2
- TTC13 | c.126C>G p.G42= | Silent (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2, varscan2
- TTN | c.19686C>G p.G6562= (on ENST00000591111; = p.G5635= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/183 reads (17%) | called by muse, mutect2, varscan2
- AC124067.2 | n.141-15T>A | Intron (SNP) | VAF 69/168 reads (41%) | called by muse, mutect2, varscan2
- ACSM2B | c.*511A>G | 3'UTR (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- ADGRL4 | c.*587T>G | 3'UTR (SNP) | VAF 25/119 reads (21%) | called by muse, mutect2, varscan2
- AL109933.2 | n.8T>C | RNA (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- ANO3 | c.*1177A>C | 3'UTR (SNP) | VAF 19/52 reads (37%) | called by muse, mutect2, varscan2
- AP001993.1 | chr11:127100329 G>C | 3'Flank (SNP) | VAF 45/148 reads (30%) | called by muse, mutect2, varscan2
- B4GALNT1 | c.712+75G>T | Intron (SNP) | VAF 14/149 reads (9%) | called by muse, mutect2
- B4GALNT4 | c.*14C>A | 3'UTR (SNP) | VAF 10/77 reads (13%) | called by muse, mutect2, varscan2
- BOD1P2 | n.395T>G | RNA (SNP) | VAF 16/109 reads (15%) | called by muse, mutect2, varscan2
- CASD1 | c.*627C>T | 3'UTR (SNP) | VAF 13/118 reads (11%) | called by muse, mutect2, varscan2
- CCND1 | c.-121C>A | 5'UTR (SNP) | VAF 18/55 reads (33%) | called by muse, mutect2, varscan2
- CD8A | c.*65C>T | 3'UTR (SNP) | VAF 12/181 reads (7%) | called by muse, mutect2
- CDON | c.*825C>G | 3'UTR (SNP) | VAF 13/101 reads (13%) | called by muse, mutect2, varscan2
- CLDN2 | c.*1849G>A | 3'UTR (SNP) | VAF 15/26 reads (58%) | catalogued as rs1395792399; called by muse, mutect2, varscan2
- CLEC5A | c.*178A>T | 3'UTR (SNP) | VAF 21/132 reads (16%) | called by muse, mutect2, varscan2
- CRB2 | c.*88A>T | 3'UTR (SNP) | VAF 13/89 reads (15%) | called by muse, mutect2, varscan2
- EBF1 | c.*2382G>A | 3'UTR (SNP) | VAF 14/29 reads (48%) | called by muse, mutect2, varscan2
- GAN | c.*1688C>T | 3'UTR (SNP) | VAF 6/56 reads (11%) | catalogued as rs1168549234; called by muse, mutect2
- GPR132 | c.-556G>T | 5'UTR (SNP) | VAF 44/134 reads (33%) | called by muse, mutect2, varscan2
- GPR83 | c.*290del | 3'UTR (DEL) | VAF 11/109 reads (10%) | called by mutect2, pindel, varscan2
- GRB10 | c.1195-83T>A | Intron (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2, varscan2
- GRIN2A | c.*2332G>A | 3'UTR (SNP) | VAF 32/88 reads (36%) | catalogued as rs1286009290; called by muse, mutect2, varscan2
- H2AZ2 | chr7:44827470 A>G | 3'Flank (SNP) | VAF 4/73 reads (5%) | called by muse, mutect2
- HIP1 | c.*1314G>T | 3'UTR (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2, varscan2
- HRCT1 | c.*441T>G | 3'UTR (SNP) | VAF 6/53 reads (11%) | called by muse, mutect2, varscan2
- HTR2C | c.*676A>C | 3'UTR (SNP) | VAF 20/29 reads (69%) | called by muse, mutect2, varscan2
- HTRA3 | c.*168G>A | 3'UTR (SNP) | VAF 26/70 reads (37%) | catalogued as rs1468673170; called by muse, mutect2, varscan2
- IGLL5 | c.-99G>A | 5'UTR (SNP) | VAF 29/68 reads (43%) | catalogued as rs192387679, COSV73249145; called by muse, mutect2, varscan2
- IRS2 | c.*219G>T | 3'UTR (SNP) | VAF 34/78 reads (44%) | called by muse, mutect2, varscan2
- ISL1 | c.-162G>T | 5'UTR (SNP) | VAF 28/73 reads (38%) | called by muse, mutect2, varscan2
- KCTD20 | c.*1238C>T | 3'UTR (SNP) | VAF 7/103 reads (7%) | called by muse, mutect2
- KCTD20 | c.*1240A>T | 3'UTR (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- KLHL42 | c.*2193T>G | 3'UTR (SNP) | VAF 4/18 reads (22%) | catalogued as rs1360146092, COSV67145630; called by muse, varscan2
- KMT2D | c.*723T>A | 3'UTR (SNP) | VAF 10/66 reads (15%) | called by muse, mutect2, varscan2
- LAIR1 | c.*836C>T | 3'UTR (SNP) | VAF 25/76 reads (33%) | catalogued as rs1036052520; called by muse, mutect2, varscan2
- LARP4 | c.*812C>G | 3'UTR (SNP) | VAF 28/100 reads (28%) | called by muse, mutect2, varscan2
- LBR | c.*818A>T | 3'UTR (SNP) | VAF 11/112 reads (10%) | called by muse, mutect2, varscan2
- LRIT1 | c.*33G>A | 3'UTR (SNP) | VAF 25/59 reads (42%) | called by muse, mutect2, varscan2
- LTB | c.163-77C>T | Intron (SNP) | VAF 83/239 reads (35%) | catalogued as COSV53002587; called by muse, mutect2, varscan2
- MAN2A1 | c.-137A>T | 5'UTR (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2, varscan2
- MARCHF1 | c.163-99C>G | Intron (SNP) | VAF 24/236 reads (10%) | catalogued as rs146137858; called by muse, mutect2, varscan2
- METTL9 | c.*825T>G | 3'UTR (SNP) | VAF 9/53 reads (17%) | called by muse, varscan2
- MYOCD | chr17:12764649 C>T | 3'Flank (SNP) | VAF 8/41 reads (20%) | called by muse, mutect2, varscan2
- NAB2 | c.*652C>A | 3'UTR (SNP) | VAF 7/83 reads (8%) | called by muse, mutect2
- NTRK3 | c.*16043C>T | 3'UTR (SNP) | VAF 16/135 reads (12%) | catalogued as COSV65103568; called by muse, mutect2, varscan2
- PARP3 | c.-309C>A | 5'UTR (SNP) | VAF 9/171 reads (5%) | called by muse, mutect2
- PHLDA1 | c.-414G>A | 5'UTR (SNP) | VAF 48/122 reads (39%) | called by muse, mutect2, varscan2
- PHLDB1 | c.-18C>G | 5'UTR (SNP) | VAF 15/147 reads (10%) | catalogued as rs782105327, COSV100616327; called by muse, mutect2
- PIK3C3 | c.2264-73A>G | Intron (SNP) | VAF 14/37 reads (38%) | catalogued as rs1395170729; called by mutect2, varscan2
- PPP1R9A | c.*4492T>A | 3'UTR (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
- PREX2 | c.*2359C>A | 3'UTR (SNP) | VAF 20/69 reads (29%) | called by muse, mutect2, varscan2
- RFPL3 | c.-30T>A | 5'UTR (SNP) | VAF 22/199 reads (11%) | called by muse, mutect2, varscan2
- ROCK1 | c.*609T>A | 3'UTR (SNP) | VAF 48/333 reads (14%) | called by muse, mutect2, varscan2
- SERPINA10 | c.*682A>C | 3'UTR (SNP) | VAF 36/108 reads (33%) | called by muse, mutect2, varscan2
- SLC16A2 | c.*2192del | 3'UTR (DEL) | VAF 5/39 reads (13%) | catalogued as COSV99330689; called by mutect2, pindel, varscan2
- SLC25A39 | c.692-44T>A | Intron (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2, varscan2
- SLC5A12 | c.*3751C>G | 3'UTR (SNP) | VAF 6/95 reads (6%) | called by muse, mutect2
- SLCO1B1 | c.-18G>T | 5'UTR (SNP) | VAF 82/235 reads (35%) | called by muse, mutect2, varscan2
- SNX1 | c.*814G>A | 3'UTR (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- SULT1A2 | c.595-23C>T | Intron (SNP) | VAF 37/92 reads (40%) | catalogued as rs748850872, COSV57682132; called by muse, mutect2, varscan2
- THY1 | c.*473T>C | 3'UTR (SNP) | VAF 18/202 reads (9%) | called by muse, mutect2
- TMOD2 | c.*6480A>C | 3'UTR (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2, varscan2
- TPO | c.*39C>T | 3'UTR (SNP) | VAF 29/261 reads (11%) | called by muse, mutect2, varscan2
- UBE2H | c.*621T>G | 3'UTR (SNP) | VAF 16/61 reads (26%) | called by muse, mutect2, varscan2
- VPS13A | c.6378+457G>A | Intron (SNP) | VAF 9/27 reads (33%) | catalogued as rs928286937; called by muse, mutect2, varscan2
- ZADH2 | c.*4740G>T | 3'UTR (SNP) | VAF 5/28 reads (18%) | called by muse, mutect2, varscan2
- ZFHX3 | c.-897+3480C>A | Intron (SNP) | VAF 43/138 reads (31%) | catalogued as rs1246536349; called by muse, mutect2, varscan2
- ZIC3 | c.*584A>T | 3'UTR (SNP) | VAF 35/95 reads (37%) | called by muse, mutect2, varscan2
- ZNF451 | chr6:57090153 C>T | 5'Flank (SNP) | VAF 16/51 reads (31%) | called by muse, mutect2, varscan2
- ZNF583 | chr19:56425111 C>G | 3'Flank (SNP) | VAF 10/68 reads (15%) | called by muse, mutect2, varscan2
